Surgical pathology report (de-identified scan), TCGA case TCGA-IM-A3ED, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Miami, specimen TCGA-IM-A3ED-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Name:

DOB:

Gender:

MRN:

Location:

Physician:

(Age:

F

Case #:

Collected:

Received:

Reported:

Copy To:

Pathologic Interpretation:

- A. Left thyroid lobe with nodule:
-Papillary thyroid carcinoma, 1.7 cm.
-Margins are free of tumor.
-Chronic lymphocytic thyroiditis.
- B. Portion of midline nodule; parathyroid versus lymph node:
-No carcinoma seen in one lymph node (0/1).
- C. Thyroid isthmus:
-No carcinoma seen in thyroid parenchyma.
-Chronic lymphocytic thyroiditis.
- D. Right lobe of thyroid:
-No carcinoma seen in thyroid parenchyma.
-Chronic lymphocytic thyroiditis.
- E. Right paratracheal node:
-No carcinoma seen in five lymph nodes (0/5).
- F. Left upper paratracheal node:
-No carcinoma seen in three lymph nodes (0/3).

1CA-0-3

TUMOR SUMMARY

Specimen type: Total thyroidectomy

Tumor site: Left lobe

Tumor focality: Unifocal

Tumor size

Greatest dimension: 1.7 cm

Additional dimensions: 1.5 x 0.7 cm

Histologic type: Papillary carcinoma

Pathologic staging

Primary tumor: pT1

Regional lymph nodes: pN0

Number examined: 9

Number involved: 0

Distant metastasis: pMX

Margins: Uninvolved by carcinoma

Venous/Lymphatic (Large/Small Vessel) Invasion: Absent

Additional Pathologic Findings: Thyroiditis

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw
10/26/11

AJCC: pT1 N0 MX

[page 2 of 2]
Intraoperative Consultation

BFS: Lymph node, no malignancy seen.

Clinical History:

Patient is a -year old white female with history of thyroid nodule.

Pre Operative Diagnosis:

Thyroid nodule

Specimen(s) Received:

- A: Left thyroid lobe with nodule
- B: Portion of midline nodule; parathyroid versus lymph node
- C: Thyroid isthmus
- D: Right lobe of thyroid
- E: Right paratracheal node
- F: Left upper paratracheal and mediastinal nodes

Gross Description:

- A. Received in formalin and labeled "left thyroid lobe with nodule" is an unoriented, partial thyroidectomy specimen, which weighs 4.8 grams and measures 3.0 x 2.7 x 0.5 cm. There is a tan, granular, well-circumscribed nodule that extends to the capsule and measures 1.7 x 1.5 x 0.7 cm. The nodule has been submitted in toto in cassettes 1-5.
- B. Received fresh and labeled "portion of midline nodule; parathyroid versus lymph node" is a tan, soft tissue specimen measuring 0.4 x 0.3 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- C. Received in formalin and labeled "thyroid isthmus" is a soft tissue measuring 1.8 x 1.0 x 0.4 cm. Specimen bisected and submitted in toto in one cassette.
- D. Received in formalin and labeled "right tobe of thyroid" is an unoriented partial thyroidectomy specimen inked in black, which measures 2.5 x 1.5 x 1.0 cm. The specimen has been serially sectioned to reveal an unremarkable parenchyma. Representative sections submitted in two cassettes.
- E. Received in formalin and labeled "right paratracheal node" is a fibroadipose tissue specimen measuring 1.2 x 0.6 x 0.4 cm, which contains lymph nodes. The specimen is bisected and submitted in cassette one along with the remainder of the tissue submitted in toto.
- F. Received in formalin and labeled "left upper paratracheal node" is a fibroadipose specimen measuring 3.2 x 1.8 x 1.0 cm. No lymph nodes were identified grossly. Stromal sections submitted in cassettes 1-3.

ICD-9(s): 193.245.2

bw 10/25/11

Source: NCI Genomic Data Commons file cb2037c4-35fa-4b40-8339-bf64aa949ab4 (TCGA-IM-A3ED.0B417B72-0AD2-4B67-ADB3-E6156572D787.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).